Surgical pathology report (de-identified scan), TCGA case TCGA-A4-A6HP, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A4-A6HP-01A (Primary Tumor).

[page 1 of 2]
Sex: Male
D.O.B.:
MRN #:

SPECIMEN INFO

Collected:
Received:
Reported:

SURGICAL PATHOLOGY REPORT

*** ADDENDUM ***

ADDENDUM REPORT:

This addendum is issued to clarify the surgical margins status. This case was discussed with Dr. Per Dr. the specimen submitted as deep margin (B) was taken from the left lateral tumor (specimen C). The left lateral tumor is not transected in the histologic sections examined. Multiple satellite foci (greater than 10) are noted in the renal parenchyma surrounding the three main lesions in specimen C-E. Some of these satellite lesions measure less than 1 mm. Therefore it is possible that the deep margin tumor in specimen B represents a separate focus of tumor rather than a positive margin from the left lateral tumor since the left lateral tumor was not transected. A conversation with Dr. also reveals that the upper pole tumor (D) was adherent to the specimen submitted as left cyst wall (A). The upper pole tumor showed an area of capsular retraction with ink focally extending to the tumor. This additional information from Dr. makes it likely that this area of concern was the site of the adherent cyst and therefore does not represent a true margin.

In summary, no tumor transection is noted, however, this patient is at increased risk for recurrence due to the numerous small satellite lesions noted.

Addendum Report Issued By:

DIAGNOSIS:

DIAGNOSIS:

A. Left cyst wall; excision:
Simple cyst wall, negative for malignancy.

B. Deep margin:
Papillary renal cell carcinoma.

C. Left lateral tumor; resection:
Tumor Characteristics:

1. Histologic type: Papillary renal cell carcinoma.
2. Tumor site: Left lateral kidney.
3. Tumor focality: Multifocal.
4. Size of largest tumor focus: 2.9 x 2.6 x 2.1 cm.
5. Macroscopic extent of tumor: Tumor limited to kidney.
6. Microscopic extent of tumor: Tumor limited to kidney.
7. Nuclear grade: Fuhrman grade 2 of 4.
8. Lymphovascular space invasion: Not identified.

Surgical Margin Status:

1. Soft tissue surgical margins free of tumor, see specimen B for separately submitted deep margin.

Lymph Node Status:

1. No lymph nodes received with specimen.

Other:

1. pTNM stage: pT1a, NX.

D. Upper pole tumor; resection:

Papillary renal cell carcinoma, 1.8 cm in greatest dimension, multifocal.
Tumor focally extends to inked capsular surface, see comment.

E. Lower pole tumor; resection:

Papillary renal cell carcinoma, 2.5 cm in greatest dimension, multifocal.
Surgical margins free of tumor.

ICD-O-3
Carcinoma, papillary
renal cell 8260/3
Site @ Kidney NOS
C64.9
JAD 6/12/13

Electronic Signature:

[page 2 of 2]
Histologic sections show numerous foci of papillary renal cell carcinoma. Each of the resections including the left lateral, upper pole, and lower poles excisions demonstrate a dominant primary tumor with multiple smaller foci within the adjacent renal parenchyma. The separately submitted deep margin (specimen B) also demonstrates similar morphology consistent with papillary renal cell carcinoma. The cyst wall is negative for tumor.

Specimen D (upper pole tumor) demonstrates tumor extending to the inked outer/capsular surface, however the capsule appears to have retracted in this area and the presence of ink at the tumor is interpreted as a retraction artifact and not a true positive capsular/soft tissue margin.

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Left renal cyst, left renal mass

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Left cyst wall
- B. Deep margin
- C. Left lateral tumor
- D. Upper pole tumor
- E. Lower pole tumor

SPECIMEN DATA

GROSS DESCRIPTION:

A. Received in formalin labeled _____ and left cyst wall is a 4.2 x 1.5 x 0.2 cm irregular piece of thin membranous tissue consistent with cyst wall. On section a lesion is not identified. Representative sections are submitted in one cassette

B. Received in formalin labeled _____ and deep margin is a 0.2 cm pink fragment submitted intact in one cassette

C. Received in formalin labeled _____ and left lateral tumor is a 24.4 gram wedge of renal tissue, 4.5 x 3.2 x 1.8 cm. The resection margin is inked blue and the soft tissue and capsule yellow. The specimen has been previously incised for research. Further section displays a circumscribed soft yellow lesion, 2.9 x 2.6 x 2.1 cm. The lesion is 0.2 cm from the resection margin and abuts the inked capsule. The remainder of the tissue is smooth homogeneous tan renal parenchyma.

Representative sections are submitted as follows: 1-2--perpendicular section through resection margin bisected; 3-4--perpendicular section through section margin bisected; 5--representative sections through perinephric adipose tissue. _____ two cassettes for research are labeled

D. Received in formalin labeled _____ and upper pole tumor is a 4.9 gram wedge of renal tissue, 3.8 x 2.0 x 1.6 cm. It is covered by a smooth capsule inked black. The resection margin is tan-pink shaggy and displays a 1.5 cm long by 0.9 cm in diameter disrupted cyst. The resection margin is inked blue. The specimen is serially sectioned to display a circumscribed focally hemorrhagic yellow bulging nodule, 1.8 x 1.5 x 1.5 cm. It is 0.2 cm from the cyst and less than 0.1 cm from the inked capsule and resection margin. The uninvolved tissue is tan-brown smooth and homogeneous. The entire specimen is sequentially submitted in four cassettes

E. Received in formalin labeled _____ and lower pole tumor is a 12.5 gram wedge of renal tissue, 5.4 x 3.5 x 2.5 cm. The specimen is covered by a complete, intact capsule. The resection margin is tan-brown and homogeneous. The capsule is inked black and the resection margin blue. The specimen is serially sectioned to show a focally hemorrhagic pale yellow soft circumscribed lesion, 2.5 x 2.1 x 1.6 cm. The lesion abuts the capsule and is 0.3 cm from the resection margin. The uninvolved tissue is tan-pink and homogenous. Representative sections to include perpendicular sections through the resection margin are submitted in four cassettes.

HPA Discrepancy		

Source: NCI Genomic Data Commons file c2d5d2b7-3522-456b-9b30-23c693b465f2 (TCGA-A4-A6HP.B874087C-F4C7-456F-AC63-E17A98F1666F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).